Somatic mutation profile of tumor specimen TCGA-P3-A6SW-01A (aliquot TCGA-P3-A6SW-01A-11D-A34J-08) from TCGA case TCGA-P3-A6SW, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 50.7 years (18,536 days).
Specimen TCGA-P3-A6SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0bfcc4c-f563-456f-bc05-2632e7611a5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6SW-10A (Blood Derived Normal), aliquot TCGA-P3-A6SW-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35f0e1ef-cae1-42fa-b421-404dc8fb9a14

The open-access MAF lists 92 somatic variants for this specimen: 68 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 22, Nonsense Mutation 8, 3'UTR 1, RNA 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 14/191 reads (7%) | catalogued as rs1369821061, COSV100846211; ClinVar: pathogenic; called by muse, mutect2
- POLG | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs867038717, CM033444, COSV99174720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866744213, COSV63661355; called by muse, mutect2
- ADGRE5 | c.262A>T p.S88C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99662875; called by muse, mutect2, varscan2
- AP1AR | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99914154; called by muse, mutect2
- BRPF3 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.85); catalogued as rs566788021, COSV100325807; called by muse, mutect2, varscan2
- C4BPA | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs1192299393, COSV100891198; called by muse, mutect2
- CFAP44 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99869427; called by muse, mutect2
- CLEC4F | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV99713708; called by muse, mutect2, varscan2
- COIL | c.1340C>G p.S447C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99538144; called by muse, mutect2, varscan2
- CREBRF | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1260400811, COSV99755754; called by muse, mutect2, varscan2
- CRISP1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100236817; called by muse, mutect2, varscan2
- CRISP2 | c.636T>G p.S212R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100189002; called by muse, mutect2
- CTNNB1 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV100846207; called by muse, mutect2
- CTNND2 | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs968695651, COSV58926447; called by muse, mutect2, varscan2
- CWH43 | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56937761, COSV56941455; called by muse, mutect2, varscan2
- DCAF5 | c.1205A>T p.H402L | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100432422; called by muse, mutect2, varscan2
- F9 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs757868547, CM940595, COSV54378910; called by muse, mutect2, varscan2
- FAM135B | c.12A>G p.I4M | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV99357015; called by muse, mutect2, varscan2
- FREM1 | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV101084346; called by muse, mutect2, varscan2
- FSTL5 | c.1650C>G p.D550E | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.757); catalogued as rs1284756527, COSV60217659; called by muse, mutect2
- GRIA4 | c.2481G>C p.L827F | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV56897782, COSV99231002; called by muse, mutect2, varscan2
- IGKV1D-8 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1176998765; called by muse, mutect2, varscan2
- IQCN | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767111124, COSV100828262; called by muse, mutect2, varscan2
- LAMA5 | c.6638C>T p.A2213V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99439670; called by muse, mutect2, varscan2
- LMNA | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs1406523929, CM078079, COSV100738642; called by muse, mutect2, varscan2
- LRP1B | c.7943C>T p.S2648F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV101256082; called by muse, mutect2
- MACF1 | c.10276G>T p.E3426* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99243799; called by muse, mutect2, varscan2
- MMP21 | c.1176C>A p.H392Q | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1446529277, COSV100916676; called by muse, mutect2
- MYH6 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV62451008; called by muse, mutect2, varscan2
- NDUFB8 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs1216537274, COSV100144095, COSV100144110; called by muse, mutect2
- NTHL1 | c.173C>T p.P58L (on ENST00000219066; = p.P50L on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs139165943; ClinVar: uncertain significance; called by mutect2, varscan2
- OR8J3 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100040790; called by muse, mutect2
- PCDHA13 | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); catalogued as COSV99165947; called by muse, mutect2
- PDZD2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs368272828; called by muse, mutect2, varscan2
- PIK3CG | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as rs867282260, COSV100782716, COSV63249428; called by muse, mutect2, varscan2
- PKHD1 | c.10785C>G p.I3595M | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100944164; called by muse, mutect2
- PLXNB1 | c.4576C>T p.Q1526* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | catalogued as COSV99602766; called by muse, mutect2
- POLQ | c.3586C>G p.L1196V | Missense Mutation (SNP) | VAF 15/401 reads (4%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.028); catalogued as COSV99952137; called by muse, mutect2
- PTGFRN | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as rs537971311, COSV67798174; called by muse, mutect2, varscan2
- PTPRD | c.4786G>T p.V1596F | Missense Mutation (SNP) | VAF 19/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100644553; called by muse, mutect2
- PTPRF | c.5462A>T p.Q1821L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1171906145, COSV100740850; called by muse, mutect2, varscan2
- RCBTB2 | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100749582; called by muse, varscan2
- RSPH1 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99370470; called by muse, mutect2
- SCN1A | c.4695G>C p.Q1565H (on ENST00000303395 / NM_001202435.3; = p.Q1554H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57667791; called by muse, mutect2, varscan2
- SLC35A4 | c.748T>G p.S250A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV100021285; called by muse, mutect2, varscan2
- SLC3A1 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as COSV99576131; called by muse, mutect2, varscan2
- SLC7A8 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100382314; called by muse, mutect2, varscan2
- SLC8A3 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141504535, COSV63519536; called by muse, mutect2, varscan2
- SLITRK5 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV61521569; called by muse, mutect2
- STK11 | c.320A>T p.H107L | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100480232, COSV58822631; called by muse, mutect2
- STK33 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100173958; called by muse, mutect2
- SULF1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99482912; called by muse, mutect2
- TCHH | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV100915012; called by muse, mutect2, varscan2
- TMEM33 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs766584485, COSV52562958; called by muse, mutect2, varscan2
- TSPYL5 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1409506792, COSV59070965; called by muse, mutect2
- VGLL4 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99809623; called by muse, mutect2, varscan2
- VPS33B | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 20/321 reads (6%) | catalogued as rs368124813, CM065517; called by muse, mutect2
- XIRP2 | c.4484A>T p.E1495V (on ENST00000628543; = p.E1670V on NM_152381.6) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV99742206; called by muse, mutect2
- ZFP90 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV101238755; called by muse, mutect2
- ZNF440 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100407513; called by muse, mutect2, varscan2
- ARHGEF26 | c.1682A>G p.E561G | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAND1 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGHV1OR15-9 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- MGRN1 | c.820A>C p.N274H | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); called by muse, mutect2
- MRC1 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- SCAF4 | c.2000dup p.P668Sfs*106 | Frame Shift Ins (INS) | VAF 34/168 reads (20%) | called by mutect2, pindel, varscan2
- SMC1A | c.173_187del p.V58_R62del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- ARID2 | c.153C>T p.Y51= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100536031; called by muse, mutect2, varscan2
- ARMC8 | c.159G>A p.Q53= (on ENST00000469044 / NM_001363941.2; = p.Q39= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/170 reads (4%) | called by muse, mutect2
- CACNG4 | c.129C>T p.G43= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100047545; called by muse, mutect2
- CAPZA2 | c.471C>T p.C157= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100753899; called by muse, mutect2, varscan2
- DMXL2 | c.6207C>T p.L2069= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV99196289; called by muse, mutect2, varscan2
- ERC1 | c.1551T>C p.A517= (on ENST00000360905 / NM_178040.4; = p.A489= on NM_178039.4) | Silent (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- GJC3 | c.153C>T p.F51= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV57210640; called by muse, mutect2
- KLHL25 | c.726G>A p.P242= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs534171698, COSV100563559; called by muse, mutect2, varscan2
- MROH2B | c.273G>A p.V91= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV101270651; called by muse, mutect2, varscan2
- OSR1 | c.333C>G p.L111= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1365237026, COSV99693661; called by muse, mutect2, varscan2
- OVGP1 | c.540G>A p.L180= | Silent (SNP) | VAF 17/209 reads (8%) | catalogued as COSV100868114; called by muse, mutect2
- PXDNL | c.564G>T p.L188= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100683361, COSV62495573; called by muse, mutect2, varscan2
- SATB2 | c.1398G>A p.S466= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs377059710; called by muse, mutect2, varscan2
- SLFN13 | c.1020C>T p.P340= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV99539966; called by muse, mutect2
- SOX3 | c.567C>T p.I189= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100983667; called by muse, mutect2, varscan2
- SYNE1 | c.10812G>A p.E3604= (on ENST00000367255 / NM_182961.4; = p.E3611= on NM_033071.3) | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV99562141; called by muse, mutect2
- SYTL5 | c.1020T>A p.T340= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV99937172; called by muse, mutect2, varscan2
- TAF1L | c.5031G>A p.T1677= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs763903524, COSV54264307; called by muse, mutect2
- TRIO | c.7689G>A p.T2563= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs764670811, COSV100702551; called by mutect2, varscan2
- TUFM | c.1221G>A p.L407= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100492570; called by muse, mutect2, varscan2
- VPS13B | c.4410G>A p.E1470= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs781336187, COSV100661837; called by muse, mutect2, varscan2
- ZNF318 | c.5814C>G p.L1938= | Silent (SNP) | VAF 9/205 reads (4%) | catalogued as COSV100546143; called by muse, mutect2
- ATRIP | c.*965G>C | 3'UTR (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99603963; called by muse, mutect2, varscan2
- UBTFL2 | n.366C>T | RNA (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
